Somatic mutation profile of tumor specimen MMRF_1358_1_BM_CD138pos (aliquot MMRF_1358_1_BM_CD138pos_T2_KAS5U_L02370) from MMRF case MMRF_1358, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.6 years (27,262 days).
Specimen MMRF_1358_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c74d4a4f-a257-43fd-a235-474e80876c74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1358_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1358_1_PB_Whole_C3_KAS5U_L02378; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69f73796-ef3b-4407-8e42-98b00a82ff64

The open-access MAF lists 146 somatic variants for this specimen: 61 protein-altering or splice-affecting, 15 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, 3'UTR 42, Intron 19, Silent 15, 5'UTR 5, Nonsense Mutation 4, Frame Shift Del 4, Splice Region 2, 3'Flank 2, Splice Site 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 50/104 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP1A3 | c.3038G>T p.R1013L (on ENST00000545399 / NM_001256214.2; = p.R1000L on NM_152296.5) | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV57484978; called by muse, mutect2, varscan2
- CABP2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140767804; called by muse, mutect2, varscan2
- CHAT | c.1535T>C p.I512T | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs769232976; called by muse, mutect2
- COL7A1 | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs996046539; called by muse, mutect2, varscan2
- CPS1 | c.80A>G p.Q27R | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1279373364; called by muse, mutect2
- DNAH7 | c.6859G>A p.A2287T | Missense Mutation (SNP) | VAF 118/293 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs778594893; called by muse, mutect2, varscan2
- DOK4 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54672202; called by muse, mutect2, varscan2
- GOLGB1 | c.1990A>G p.T664A | Missense Mutation (SNP) | VAF 125/402 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs567769952; called by muse, mutect2, varscan2
- GRM7 | c.919C>A p.H307N | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100736619; called by muse, mutect2, varscan2
- HCRTR2 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV100904056; called by muse, mutect2, varscan2
- IGHD3-9 | c.1G>A p.V1I | Missense Mutation (SNP) | VAF 14/16 reads (88%) | catalogued as rs373641757; called by muse, varscan2
- IGHV1-69 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.446); catalogued as rs782696214; called by muse, varscan2
- IGHV2-70 | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs370193821; called by muse, varscan2
- IGHV2-70D | c.335C>G p.A112G | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs1456429000; called by muse, varscan2
- IGLV3-1 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs184648956; called by muse, mutect2, varscan2
- KIF2B | c.756G>T p.K252N | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1201030504; called by muse, mutect2, varscan2
- MAG | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 98/146 reads (67%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs1027874006, COSV62699725, COSV62700893; called by muse, mutect2, varscan2
- NOCT | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 53/100 reads (53%) | catalogued as rs765534383, COSV54936197; called by muse, mutect2, varscan2
- PBRM1 | c.2530A>G p.M844V | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as rs1313358258; called by muse, mutect2
- PCDH1 | c.3520C>T p.P1174S | Missense Mutation (SNP) | VAF 81/117 reads (69%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1350267982; called by muse, mutect2, varscan2
- PKMYT1 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs537845943; called by muse, mutect2, varscan2
- RAD18 | c.603A>C p.K201N | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs752890457; called by muse, mutect2, varscan2
- RYR2 | c.13387A>G p.R4463G | Missense Mutation (SNP) | VAF 57/216 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as COSV100771486; called by muse, mutect2, varscan2
- SMARCE1 | c.8-2A>G p.X3_splice | Splice Site (SNP) | VAF 24/94 reads (26%) | catalogued as rs1362767793; called by muse, mutect2, varscan2
- SRRM2 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 10/350 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV57073005; called by muse, mutect2
- SYT3 | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58895973; called by muse, mutect2, varscan2
- TNC | c.3987G>T p.E1329D | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.267); catalogued as rs776430821; called by muse, mutect2, varscan2
- TRANK1 | c.2675C>T p.T892M | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368621710; called by muse, mutect2, varscan2
- ZNF365 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.744); catalogued as rs779285297, COSV101237963, COSV67925670; called by muse, mutect2, varscan2
- ADGRL1 | c.907G>A p.E303K (on ENST00000340736 / NM_001008701.3; = p.E298K on NM_014921.5) | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANAPC4 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); called by muse, mutect2
- ANLN | c.2438T>A p.L813Q | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APLP1 | c.1892T>A p.L631H (on ENST00000221891 / NM_001024807.3; = p.L630H on NM_005166.4) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APPBP2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.835); called by muse, mutect2
- BTAF1 | c.4834C>T p.H1612Y | Missense Mutation (SNP) | VAF 124/272 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.602_608del p.T201Sfs*51 | Frame Shift Del (DEL) | VAF 147/350 reads (42%) | called by mutect2, pindel, varscan2
- CFAP69 | c.202_206del p.L68Ifs*23 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- FSIP2 | c.2320T>A p.C774S | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- GAREM1 | c.1232del p.G411Efs*62 | Frame Shift Del (DEL) | VAF 42/127 reads (33%) | called by pindel, varscan2
- GPX4 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 65/211 reads (31%) | called by muse, mutect2, varscan2
- LCE2A | c.183C>A p.S61R | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- LZIC | c.265T>G p.F89V | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- MECOM | c.31A>G p.M11V (on ENST00000468789 / NM_001105078.4; = p.M199V on NM_004991.4) | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- MIEF1 | c.1111T>G p.C371G | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYO10 | c.4753C>A p.P1585T | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- NETO1 | c.1162T>C p.F388L | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NF1 | c.5045_5046del p.C1682* (on ENST00000358273 / NM_001042492.3; = p.C1661* on NM_000267.3) | Frame Shift Del (DEL) | VAF 27/125 reads (22%) | called by mutect2, pindel, varscan2
- NSMAF | c.1216+2T>C p.X406_splice | Splice Site (SNP) | VAF 30/125 reads (24%) | called by muse, mutect2, varscan2
- NSMCE2 | c.-12A>G | Splice Region (SNP) | VAF 72/253 reads (28%) | called by muse, mutect2, varscan2
- SARNP | c.28A>T p.K10* | Nonsense Mutation (SNP) | VAF 88/197 reads (45%) | called by muse, mutect2, varscan2
- SEL1L3 | c.158A>T p.Y53F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2
- SLC6A7 | c.1037G>C p.G346A | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPOCK3 | c.1124A>G p.N375S | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.022); called by muse, mutect2
- TAFA4 | c.143T>A p.I48N | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- THBS2 | c.919C>A p.L307I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- TMTC4 | c.2003dup p.Y668* (on ENST00000376234 / NM_001350577.2; = p.Y687* on NM_032813.5 and 2 other RefSeq transcripts) | Nonsense Mutation (INS) | VAF 35/103 reads (34%) | called by mutect2, pindel, varscan2
- TNNC1 | c.203-3C>G | Splice Region (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- TTN | c.87005C>A p.A29002D (on ENST00000591111; = p.A21578D on NM_003319.4) | Missense Mutation (SNP) | VAF 28/182 reads (15%) | PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- ZFPM2 | c.2410A>G p.T804A | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF384 | c.1040G>A p.C347Y | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ANKRD50 | c.102G>A p.Q34= | Silent (SNP) | VAF 90/243 reads (37%) | called by muse, mutect2, varscan2
- CDH3 | c.2322C>T p.Y774= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as rs958988261; called by muse, mutect2
- GAREM1 | c.1225C>T p.L409= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV99329964; called by muse, varscan2
- IGHV2-70 | c.81T>A p.G27= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs530772710; called by muse, varscan2
- INPPL1 | c.1413C>A p.T471= | Silent (SNP) | VAF 40/139 reads (29%) | catalogued as rs777233012; called by muse, mutect2, varscan2
- KCNB1 | c.786C>G p.L262= | Silent (SNP) | VAF 62/143 reads (43%) | catalogued as COSV65567236; called by muse, mutect2, varscan2
- KLK8 | c.708C>A p.S236= | Silent (SNP) | VAF 39/166 reads (23%) | catalogued as COSV51590262; called by muse, mutect2, varscan2
- METTL22 | c.309G>T p.G103= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as rs1452128904; called by muse, mutect2, varscan2
- MGAM2 | c.5865T>G p.A1955= | Silent (SNP) | VAF 362/773 reads (47%) | called by muse, mutect2, varscan2
- PAQR9 | c.378G>A p.A126= | Silent (SNP) | VAF 13/328 reads (4%) | catalogued as rs1049426022, COSV61417824; called by muse, mutect2
- PDGFC | c.48G>A p.Q16= | Silent (SNP) | VAF 76/137 reads (55%) | called by muse, mutect2, varscan2
- PLCE1 | c.3474C>A p.P1158= | Silent (SNP) | VAF 37/71 reads (52%) | called by muse, mutect2, varscan2
- SLC8A2 | c.918C>T p.R306= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2
- SLITRK2 | c.912G>A p.P304= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as rs377471915; called by muse, mutect2, varscan2
- SYPL2 | c.681C>T p.A227= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs758997152; called by muse, mutect2, varscan2
- ABI3BP | c.1576+6771C>T | Intron (SNP) | VAF 29/138 reads (21%) | called by muse, mutect2, varscan2
- AC113208.3 | n.1506T>C | RNA (SNP) | VAF 27/107 reads (25%) | called by muse, mutect2, varscan2
- AMOTL2 | c.*1798C>A | 3'UTR (SNP) | VAF 12/87 reads (14%) | called by muse, varscan2
- BACH1 | c.*122A>G | 3'UTR (SNP) | VAF 43/152 reads (28%) | called by muse, mutect2, varscan2
- C3orf14 | chr3:62334880 del T | 3'Flank (DEL) | VAF 43/274 reads (16%) | called by mutect2, pindel, varscan2
- CD44 | c.*2161A>G | 3'UTR (SNP) | VAF 43/91 reads (47%) | called by muse, mutect2, varscan2
- CMKLR1 | c.*2936T>C | 3'UTR (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- COL5A1 | c.654+7436G>A | Intron (SNP) | VAF 52/245 reads (21%) | catalogued as rs762947226; called by muse, mutect2, varscan2
- CREM | c.-10T>G | 5'UTR (SNP) | VAF 11/368 reads (3%) | called by muse, mutect2
- DCTN5 | c.*1880G>A | 3'UTR (SNP) | VAF 11/63 reads (17%) | catalogued as rs1443166115; called by muse, mutect2, varscan2
- DEFB132 | c.*170G>A | 3'UTR (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- DEPDC5 | c.*1564C>T | 3'UTR (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- DGKA | c.-81-21C>T | Intron (SNP) | VAF 31/66 reads (47%) | catalogued as rs962690995; called by muse, mutect2, varscan2
- DMKN | c.1288-65G>A | Intron (SNP) | VAF 22/111 reads (20%) | called by muse, mutect2, varscan2
- EIF2S1 | c.*2551T>C | 3'UTR (SNP) | VAF 42/94 reads (45%) | called by muse, mutect2, varscan2
- EREG | c.*3682C>T | 3'UTR (SNP) | VAF 53/119 reads (45%) | catalogued as rs933666204; called by muse, mutect2, varscan2
- ESRRB | c.1501-149G>T | Intron (SNP) | VAF 30/44 reads (68%) | called by muse, varscan2
- ESRRG | c.*1082T>G | 3'UTR (SNP) | VAF 52/99 reads (53%) | called by muse, mutect2, varscan2
- FAM117B | c.*2331A>C | 3'UTR (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- FOXL2 | c.*26G>T | 3'UTR (SNP) | VAF 36/71 reads (51%) | catalogued as rs761793502; called by muse, mutect2, varscan2
- FREM2 | c.-57C>T | 5'UTR (SNP) | VAF 8/131 reads (6%) | catalogued as rs961769693; called by muse, mutect2
- GGA3 | c.1781-116C>T | Intron (SNP) | VAF 14/26 reads (54%) | catalogued as rs201025074; called by muse, mutect2, varscan2
- GIPC2 | c.*849T>A | 3'UTR (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- GRM7 | c.-80G>A | 5'UTR (SNP) | VAF 9/41 reads (22%) | catalogued as rs993821478; called by muse, mutect2, varscan2
- H2BC9 | c.*18C>T | 3'UTR (SNP) | VAF 79/191 reads (41%) | called by muse, mutect2, varscan2
- HMGCR | c.*1357A>G | 3'UTR (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- HMGXB4 | c.*1064G>A | 3'UTR (SNP) | VAF 19/57 reads (33%) | catalogued as rs1281345079; called by muse, mutect2, varscan2
- INPP4A | c.*845dup | 3'UTR (INS) | VAF 40/142 reads (28%) | catalogued as rs1276084635; called by mutect2, pindel, varscan2
- IQSEC1 | c.2848-1664C>T | Intron (SNP) | VAF 11/77 reads (14%) | catalogued as rs1454988908; called by muse, mutect2, varscan2
- IRS2 | c.*488C>T | 3'UTR (SNP) | VAF 7/104 reads (7%) | catalogued as rs1037350896; called by muse, mutect2
- ISOC2 | c.349-113C>T | Intron (SNP) | VAF 4/52 reads (8%) | catalogued as rs960812833; called by muse, mutect2
- KMT5A | c.*1389G>A | 3'UTR (SNP) | VAF 37/98 reads (38%) | catalogued as rs540625692; called by muse, mutect2, varscan2
- LINC01387 | n.305C>T | RNA (SNP) | VAF 6/62 reads (10%) | catalogued as rs964668366; called by muse, mutect2
- LTB | c.162+136G>A | Intron (SNP) | VAF 31/49 reads (63%) | catalogued as rs541787102; called by muse, mutect2, varscan2
- MAP4 | c.2000-15244A>C | Intron (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- NCKAP5L | c.3793-13C>T | Intron (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- NDRG1 | c.*1467G>T | 3'UTR (SNP) | VAF 26/118 reads (22%) | called by muse, mutect2, varscan2
- NEGR1 | c.*4264A>T | 3'UTR (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- NKTR | c.*190T>G | 3'UTR (SNP) | VAF 16/125 reads (13%) | called by muse, mutect2, varscan2
- NPDC1 | c.113-676C>T | Intron (SNP) | VAF 10/248 reads (4%) | called by muse, mutect2
- NRXN3 | chr14:79863621 T>C | 3'Flank (SNP) | VAF 47/103 reads (46%) | called by muse, mutect2, varscan2
- NTS | c.*54T>A | 3'UTR (SNP) | VAF 73/276 reads (26%) | called by muse, mutect2, varscan2
- PARP8 | c.*4247C>T | 3'UTR (SNP) | VAF 19/159 reads (12%) | called by muse, mutect2, varscan2
- PDE10A | c.*3621T>C | 3'UTR (SNP) | VAF 46/105 reads (44%) | called by muse, mutect2, varscan2
- PPP1CC | c.56-294C>T | Intron (SNP) | VAF 7/29 reads (24%) | catalogued as rs1484234198; called by muse, mutect2
- PRLR | c.*7336T>A | 3'UTR (SNP) | VAF 55/173 reads (32%) | called by muse, mutect2, varscan2
- PSD2 | c.*1052A>C | 3'UTR (SNP) | VAF 35/108 reads (32%) | called by muse, mutect2, varscan2
- REG1B | c.183+137T>G | Intron (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2
- RGS5 | c.*4432G>T | 3'UTR (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- SCARA3 | c.*1636A>G | 3'UTR (SNP) | VAF 42/105 reads (40%) | called by muse, mutect2, varscan2
- SCGB1A1 | c.*19C>T | 3'UTR (SNP) | VAF 122/340 reads (36%) | called by muse, mutect2, varscan2
- SKOR2 | c.2753-152C>T | Intron (SNP) | VAF 18/61 reads (30%) | catalogued as rs551234905; called by muse, mutect2, varscan2
- SLC16A1 | c.*271A>T | 3'UTR (SNP) | VAF 87/126 reads (69%) | called by muse, mutect2, varscan2
- SLC7A8 | c.*1759G>A | 3'UTR (SNP) | VAF 130/271 reads (48%) | called by muse, mutect2, varscan2
- SLIT3 | c.*3105A>G | 3'UTR (SNP) | VAF 10/93 reads (11%) | catalogued as rs1290205336; called by muse, mutect2, varscan2
- SLK | c.-346G>A | 5'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- TM7SF2 | c.603+97G>A | Intron (SNP) | VAF 7/13 reads (54%) | catalogued as rs1311767802; called by muse, mutect2, varscan2
- TNFRSF19 | c.*2266G>T | 3'UTR (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- TP63 | c.1350-6015G>A | Intron (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- TRIO | c.*674T>C | 3'UTR (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- TRIO | c.*675G>T | 3'UTR (SNP) | VAF 15/73 reads (21%) | catalogued as rs995813987; called by muse, mutect2, varscan2
- TSG101 | c.843+9C>T | Intron (SNP) | VAF 31/92 reads (34%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*652T>G | 3'UTR (SNP) | VAF 59/160 reads (37%) | called by muse, mutect2, varscan2
- UFM1 | c.190+241T>A | Intron (SNP) | VAF 44/104 reads (42%) | called by muse, mutect2, varscan2
- UNC5C | c.*2213T>C | 3'UTR (SNP) | VAF 30/70 reads (43%) | catalogued as rs1560708136; called by muse, mutect2, varscan2
- VPS29 | c.-19A>T | 5'UTR (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2, varscan2
- WWC3 | c.*1966T>A | 3'UTR (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- ZADH2 | c.*398G>C | 3'UTR (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- ZFP30 | c.*2295T>C | 3'UTR (SNP) | VAF 4/60 reads (7%) | catalogued as COSV63622793; called by muse, mutect2
- ZNF716 | c.*2090G>A | 3'UTR (SNP) | VAF 51/87 reads (59%) | called by muse, mutect2, varscan2
